Somatic mutation profile of tumor specimen C3L-05889-54 (aliquot CPT0344240001) from CPTAC case C3L-05889, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 49.5 years (18,083 days).
Specimen C3L-05889-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca4634de-f68b-4035-96a0-9d9dd6146532.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05889-50 (Buccal Cell Normal), aliquot CPT0344210003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e43c07b-fa0b-44c3-884b-9aa17c8363d7

The open-access MAF lists 20 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Nonsense Mutation 3, Intron 1, 3'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAHCC1 | c.2550dup p.G851Rfs*223 | Frame Shift Ins (INS) | VAF 39/129 reads (30%) | catalogued as rs1555653824; called by mutect2, pindel, varscan2
- CD1B | c.980G>C p.R327P | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.599); catalogued as COSV63804341; called by mutect2, varscan2
- LLGL1 | c.928G>C p.G310R | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100375272; called by muse, mutect2
- NAT1 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs377662129; called by muse, mutect2
- TET2 | c.4393C>T p.R1465* | Nonsense Mutation (SNP) | VAF 75/230 reads (33%) | catalogued as rs1235228377, COSV54395631; called by muse, mutect2, varscan2
- USH2A | c.3334G>C p.D1112H | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56324452; called by muse, mutect2
- DARS1 | c.482G>C p.R161P | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- DNAH9 | c.998C>G p.P333R | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2
- IGLV3-32 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KMT2C | c.11873T>A p.L3958* | Nonsense Mutation (SNP) | VAF 64/131 reads (49%) | called by muse, mutect2, varscan2
- MIA2 | c.1109G>C p.S370T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.103); called by muse, mutect2
- OR10X1 | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.101); called by muse, mutect2
- PCDHGA4 | c.1488C>G p.N496K | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTGS1 | c.162C>G p.Y54* | Nonsense Mutation (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- CALD1 | c.39A>G p.Q13= | Silent (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- GRM7 | c.375G>A p.A125= | Silent (SNP) | VAF 9/239 reads (4%) | catalogued as rs926679980, COSV63136388; called by muse, mutect2
- MPEG1 | c.1086C>T p.A362= | Silent (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- ABI3BP | c.1577-8509G>A | Intron (SNP) | VAF 13/246 reads (5%) | catalogued as rs1330871533, COSV52539876; called by muse, mutect2
- CCDC187 | c.*2663C>G | 3'UTR (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- UBE2DNL | n.596C>T | RNA (SNP) | VAF 40/62 reads (65%) | called by muse, mutect2, varscan2
